CCDI case PBCBHT — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Soft Tissue Tumors and Sarcomas, NOS; Primary site: Larynx.
https://portal.gdc.cancer.gov/cases/6bd99291-c669-4b22-b94b-ff8eda442a51

Demographics
Sex at birth: male; Race: white.

Diagnoses (1)
1. Rhabdomyosarcoma, NOS: ICD-O-3 morphology code: 8900/3; Tissue or organ of origin: Larynx, NOS; Age at diagnosis: 5.2 years (1,910 days).

Biospecimens (3 samples)
- Sample 0DN51K: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DN51S: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
- Sample 0DN52A: Tissue type: Tumor; Specimen type: Solid Tissue.
